Somatic mutation profile of tumor specimen TCGA-EK-A2RK-01A (aliquot TCGA-EK-A2RK-01A-11D-A18J-09) from TCGA case TCGA-EK-A2RK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IA2; Tumor grade: G3; Age at diagnosis: 67.2 years (24,541 days).
Specimen TCGA-EK-A2RK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc773c1e-8963-4681-a03a-7ba45b13d7fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2RK-10A (Blood Derived Normal), aliquot TCGA-EK-A2RK-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3bcbd62-e29e-4863-a384-134128cfd615

The open-access MAF lists 234 somatic variants for this specimen: 181 protein-altering or splice-affecting, 46 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 46, Nonsense Mutation 20, Intron 5, Frame Shift Del 3, Frame Shift Ins 2, Nonstop Mutation 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.12019C>T p.Q4007* | Nonsense Mutation (SNP) | VAF 18/23 reads (78%) | catalogued as rs188017299, COSV56430202; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT8 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54170531; called by muse, mutect2, varscan2
- ACSBG1 | c.1646G>A p.G549D | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51908970; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1760C>T p.A587V | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1278049723; called by muse, mutect2, varscan2
- ADAP2 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760597259, COSV58295468, COSV58296776; called by muse, mutect2, varscan2
- ADAR | c.2993G>C p.G998A | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52718863, COSV52721467; called by muse, mutect2, varscan2
- AGO4 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV64618041; called by muse, mutect2, varscan2
- AIRE | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139874934, COSV52394895; called by muse, mutect2, varscan2
- ALOX15B | c.1540G>C p.E514Q | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66479889; called by muse, mutect2, varscan2
- ALPK2 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100864785, COSV64495148; called by muse, mutect2, varscan2
- ATL3 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV60297587; called by muse, mutect2, varscan2
- ATP6V0A4 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs769417807, CM065982, COSV59472874; called by muse, mutect2, varscan2
- BOD1L1 | c.6620C>G p.S2207* | Nonsense Mutation (SNP) | VAF 16/20 reads (80%) | catalogued as COSV50035126; called by muse, mutect2, varscan2
- BRAF | c.144G>A p.W48* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV56294995; called by muse, mutect2, varscan2
- CABYR | c.92C>G p.S31* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV59111960, COSV59112058; called by muse, mutect2, varscan2
- CARD9 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs772871267, COSV59996464, COSV59997651; called by muse, mutect2, varscan2
- CARMIL2 | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58029901; called by muse, mutect2, varscan2
- CCDC141 | c.3696G>A p.M1232I | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV55378650; called by muse, mutect2, varscan2
- CCDC40 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs1314509837, COSV66477139; called by muse, mutect2, varscan2
- CCKAR | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1488720673, COSV55159744; called by muse, mutect2, varscan2
- CELSR1 | c.1826C>A p.S609Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV53096006; called by muse, mutect2, varscan2
- CEP126 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV54828700; called by muse, mutect2, varscan2
- CEP162 | c.3889G>A p.E1297K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57621741, COSV57622466; called by muse, mutect2, varscan2
- CHKB | c.523C>G p.H175D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56418126; called by muse, mutect2, varscan2
- CIDEC | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs750395115, COSV61062253; called by muse, mutect2, varscan2
- CNBD2 | c.989G>A p.R330K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.664); catalogued as COSV62586305; called by muse, mutect2
- CNGA3 | c.478G>A p.V160M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs373542579; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.8363A>C p.Q2788P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.926); catalogued as COSV59402915; called by muse, mutect2, varscan2
- CTSG | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV53536387; called by muse, mutect2, varscan2
- CUL9 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV52732212; called by muse, mutect2, varscan2
- DENND4C | c.5762G>A p.G1921E (on ENST00000434457 / NM_001330640.2; = p.G1872E on NM_017925.7) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV59548395; called by muse, mutect2, varscan2
- DIS3L2 | c.2657G>C p.*886Sext*23 | Nonstop Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as COSV56059862; called by muse, mutect2
- DMRTC2 | c.31C>T p.H11Y | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.255); catalogued as COSV54187538; called by muse, mutect2, varscan2
- DNAH1 | c.5877G>A p.M1959I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768724065, COSV70233153; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DUSP8 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV59030934; called by muse, varscan2
- EFTUD2 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs969190009, COSV68184126; called by muse, mutect2, varscan2
- ENO3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as rs1280660841, COSV56697904; called by muse, mutect2, varscan2
- ENO3 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.872); catalogued as rs757279282, COSV56697909; called by muse, mutect2, varscan2
- EP300 | c.2437C>T p.Q813* | Nonsense Mutation (SNP) | VAF 22/47 reads (47%) | catalogued as CM162044, COSV54338830; called by muse, mutect2, varscan2
- ERICH6 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV55799484, COSV55802189; called by muse, mutect2, varscan2
- ESPNL | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372806468; called by muse, mutect2, varscan2
- ESRP2 | c.1706G>A p.R569H (on ENST00000565858 / NM_001365264.1; = p.R559H on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.315); catalogued as rs949284278, COSV52175017; called by muse, mutect2, varscan2
- EXOC5 | c.2047C>G p.L683V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61771783; called by muse, mutect2, varscan2
- EZR | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.201); catalogued as rs1392571214, COSV51913361; called by muse, mutect2, varscan2
- FAM161B | c.1355G>T p.R452I (on ENST00000651776; = p.R389I on NM_152445.3) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV54103530, COSV99679653; called by muse, mutect2, varscan2
- FAM217B | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62564885; called by muse, varscan2
- FBXL20 | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 26/36 reads (72%) | catalogued as COSV52902038; called by muse, mutect2, varscan2
- FLNC | c.4987G>T p.E1663* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV57961097; called by muse, mutect2, varscan2
- FLNC | c.5911G>A p.E1971K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100367613, COSV57961107; called by muse, mutect2, varscan2
- FNDC11 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64443245; called by muse, mutect2, varscan2
- FOXK1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV61067728; called by muse, mutect2, varscan2
- FRYL | c.1393G>C p.D465H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51955798; called by muse, mutect2, varscan2
- GBP4 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1209056933, COSV63255384; called by muse, mutect2, varscan2
- GCM2 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV65275193, COSV65276206; called by muse, mutect2, varscan2
- GNAI3 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV63984259; called by muse, mutect2, varscan2
- GRIK5 | c.1915C>G p.L639V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53482858; called by muse, mutect2, varscan2
- GRIN3B | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV52262181; called by muse, mutect2
- GTF3C1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs779869561, COSV55187911; called by muse, mutect2, varscan2
- GTF3C6 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV57333164; called by muse, mutect2, varscan2
- GZMB | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53542748; called by muse, mutect2, varscan2
- HEATR4 | c.2565G>A p.M855I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs141407968, COSV58374450; called by muse, mutect2, varscan2
- HELZ2 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs563895075, COSV64410200; called by muse, mutect2, varscan2
- HEPH | c.3262A>T p.I1088F (on ENST00000343002; = p.I821F on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV57968878; called by muse, mutect2
- HIVEP1 | c.8125G>A p.D2709N | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65103806; called by muse, mutect2, varscan2
- HSD17B7 | c.649T>G p.Y217D | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54419275; called by muse, mutect2, varscan2
- HSPB7 | c.59C>G p.S20C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); catalogued as COSV100317911, COSV58893148; called by muse, mutect2, varscan2
- KIAA0100 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as COSV66495310; called by muse, mutect2, varscan2
- KIAA0100 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66495318, COSV66495454; called by muse, varscan2
- KIRREL1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs151150995; called by muse, mutect2, varscan2
- KLHL14 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63834396; called by muse, mutect2, varscan2
- KLHL4 | c.57G>C p.W19C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64145914; called by muse, mutect2, varscan2
- KLHL41 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52931158; called by muse, mutect2, varscan2
- KMT2C | c.2911G>A p.E971K | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100076616; called by muse, mutect2, varscan2
- KRT34 | c.1096C>T p.Q366* | Nonsense Mutation (SNP) | VAF 59/90 reads (66%) | catalogued as COSV67450375; called by muse, mutect2, varscan2
- KRT5 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV52862378; called by muse, mutect2, varscan2
- LCE2D | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); catalogued as COSV64229138; called by muse, mutect2, varscan2
- LHX6 | c.508G>T p.E170* (on ENST00000373755 / NM_001242334.2; = p.E199* on NM_014368.5) | Nonsense Mutation (SNP) | VAF 37/106 reads (35%) | catalogued as COSV61345511; called by muse, mutect2, varscan2
- LIG3 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.279); catalogued as rs148073351; called by muse, mutect2, varscan2
- LNPEP | c.28C>T p.Q10* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as rs758975880; called by muse, mutect2, varscan2
- LRRC4 | c.224C>G p.S75W | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.936); catalogued as rs1390988880, COSV50816452; called by muse, mutect2, varscan2
- MAGEC3 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV53580502, COSV68924080; called by muse, mutect2, varscan2
- MAML1 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as COSV52987733; called by muse, mutect2, varscan2
- MAP4 | c.3155G>A p.G1052E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53140799; called by muse, mutect2, varscan2
- MCOLN2 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as COSV52297897; called by muse, mutect2, varscan2
- MDC1 | c.784C>T p.Q262* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | catalogued as COSV64526172; called by muse, mutect2, varscan2
- MGA | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV54959651; called by muse, mutect2, varscan2
- MGAM | c.3059C>A p.S1020Y | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV72074432, COSV72075227; called by muse, mutect2, varscan2
- MGAT3 | c.1523C>T p.T508M | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as rs1403786617, COSV57867166; called by muse, mutect2, varscan2
- MPDZ | c.2766T>A p.S922R | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV59921563; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1951G>C p.D651H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56622547; called by muse, mutect2, varscan2
- MRE11 | c.1922C>A p.S641* (on ENST00000323929 / NM_005591.4; = p.S613* on NM_005590.4) | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100120077; called by muse, mutect2
- MUC5B | c.3946G>A p.A1316T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1427095732, COSV71594336; called by muse, mutect2, varscan2
- MYOCD | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs139170912; called by muse, mutect2, varscan2
- NACC2 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as rs965015333, COSV53201958; called by muse, mutect2, varscan2
- NBEAL2 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs376604123, COSV52754244, COSV52761388; called by muse, mutect2, varscan2
- NDC80 | c.1873G>C p.E625Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.178); catalogued as COSV55249083; called by muse, mutect2
- NDST4 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs760989212, COSV52127725; called by muse, mutect2, varscan2
- NFYA | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58199369; called by muse, mutect2, varscan2
- NME7 | c.134C>G p.T45S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as COSV63169191; called by muse, mutect2, varscan2
- NOTCH3 | c.2920G>A p.G974R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs747234439, COSV54628839; called by muse, mutect2, varscan2
- NPHP4 | c.2701C>T p.P901S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs886046464, COSV65396642; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUDT16L1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.817); catalogued as COSV52152990; called by muse, varscan2
- OR13C9 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV52242194, COSV52243112; called by muse, mutect2, varscan2
- OR2AE1 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV60390753; called by muse, varscan2
- OR2T10 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.378); catalogued as rs200418834, COSV57897670; called by muse, mutect2, varscan2
- OR5T3 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57381928; called by muse, mutect2, varscan2
- PCDHAC1 | c.2075C>G p.S692C | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53838602, COSV53862217; called by muse, mutect2, varscan2
- PCNT | c.8266G>T p.E2756* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV64031254; called by muse, mutect2, varscan2
- PDX1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66847357; called by muse, mutect2, varscan2
- PEX6 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs780239941, COSV55103741; called by muse, mutect2, varscan2
- PLCB1 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV62061344; called by muse, mutect2, varscan2
- PLEKHA6 | c.2764G>C p.D922H | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55338024; called by muse, mutect2, varscan2
- PNISR | c.1526G>C p.R509T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.065); catalogued as COSV65080244; called by muse, mutect2, varscan2
- POGLUT1 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV55157746; called by muse, mutect2, varscan2
- POLD3 | c.472T>C p.S158P | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1239451039, COSV55244586; called by muse, mutect2, varscan2
- POU4F3 | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV57942715; called by muse, mutect2, varscan2
- PPP1R13B | c.386C>G p.S129* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as COSV52454519, COSV52455063; called by muse, mutect2, varscan2
- PRMT2 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs904593804, COSV52457072; called by muse, mutect2, varscan2
- PRRC2A | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV63224758; called by muse, mutect2, varscan2
- PRRC2A | c.1519G>C p.E507Q | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.55); catalogued as COSV63224919; called by muse, mutect2, varscan2
- PSEN2 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV60917440, COSV60917501; called by muse, mutect2, varscan2
- PTCHD1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV65061721; called by muse, mutect2, varscan2
- PTEN | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1111458, CM131884, COSV64291957, COSV64294035, COSV64296475; called by muse, mutect2, varscan2
- PTEN | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64292105, COSV64302293; called by muse, mutect2, varscan2
- PTEN | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.383); catalogued as rs878853946, COSV64302298; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RFNG | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57650721; called by muse, mutect2, varscan2
- RFTN1 | c.650G>A p.R217K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs758444396, COSV61921661; called by muse, mutect2, varscan2
- RNF111 | c.2160C>G p.I720M | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV62088522; called by muse, mutect2, varscan2
- RSPH4A | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV57636057; called by muse, mutect2, varscan2
- RTN1 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV50723391; called by muse, mutect2, varscan2
- SAMM50 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs765107676, COSV63110365; called by muse, mutect2, varscan2
- SCAI | c.991G>C p.E331Q (on ENST00000336505 / NM_001144877.3; = p.E354Q on NM_173690.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as COSV60615811; called by muse, mutect2, varscan2
- SEC24D | c.2585C>G p.S862* | Nonsense Mutation (SNP) | VAF 46/65 reads (71%) | catalogued as COSV54882978; called by muse, mutect2, varscan2
- SERPINA4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as rs1278033042, COSV54069426; called by muse, mutect2, varscan2
- SHB | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100891906, COSV99081200; called by muse, mutect2
- SIPA1L2 | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV53395860; called by muse, varscan2
- SLC26A6 | c.2264C>T p.S755L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374322645; called by muse, mutect2, varscan2
- SOCS2 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV61392444; called by muse, mutect2, varscan2
- SORT1 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56668441, COSV99861022; called by muse, mutect2, varscan2
- SPATA6 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64062508; called by muse, mutect2, varscan2
- SPTB | c.4576G>C p.E1526Q | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67633886; called by muse, mutect2, varscan2
- STAMBPL1 | c.1385G>C p.*462Sext*10 | Nonstop Mutation (SNP) | VAF 11/19 reads (58%) | catalogued as COSV64230234; called by muse, mutect2, varscan2
- STK38 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57710072; called by muse, mutect2, varscan2
- STXBP2 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV55404808; called by muse, mutect2, varscan2
- SYNE2 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV59961727; called by muse, mutect2, varscan2
- TCEAL1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV65461206; called by muse, mutect2, varscan2
- TEK | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.984); catalogued as COSV66228644, COSV66231301; called by muse, mutect2, varscan2
- TEPSIN | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56144036; called by muse, mutect2, varscan2
- TEX11 | c.378G>A p.M126I (on ENST00000344304; = p.M111I on NM_031276.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60235524; called by muse, mutect2, varscan2
- TG | c.1617G>C p.K539N | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV55088086; called by muse, mutect2, varscan2
- TIMMDC1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV51787472; called by muse, mutect2
- TJP2 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV55271045; called by muse, mutect2, varscan2
- TMEM273 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as COSV65153689; called by muse, mutect2, varscan2
- TOPORS | c.1700C>G p.S567* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV62117731; called by muse, mutect2, varscan2
- TRAFD1 | c.980C>G p.S327C | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV57505619; called by muse, mutect2
- TRPM6 | c.5940A>C p.L1980F | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62518121; called by muse, mutect2, varscan2
- TTC30B | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV68809686; called by muse, mutect2, varscan2
- TTLL13P | c.1199C>G p.S400* | Nonsense Mutation (SNP) | VAF 32/48 reads (67%) | catalogued as COSV60039257; called by muse, mutect2, varscan2
- TTN | c.101227G>A p.E33743K (on ENST00000591111; = p.E26319K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | PolyPhen benign (0); catalogued as COSV60227221; called by mutect2, varscan2
- TTN | c.22403G>A p.C7468Y (on ENST00000591111; = p.C6541Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | PolyPhen probably damaging (0.977); catalogued as rs1315544282, COSV60227285; called by muse, mutect2, varscan2
- USP34 | c.5569G>A p.E1857K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.931); catalogued as COSV68404232; called by muse, mutect2, varscan2
- VAV2 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1177442941, COSV64083802, COSV64083968; called by muse, mutect2, varscan2
- WFDC1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.062); catalogued as COSV54745182; called by muse, mutect2, varscan2
- WNT5B | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs749569775, COSV60198636; called by muse, mutect2, varscan2
- XPC | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV53205113; called by muse, mutect2, varscan2
- ZFHX4 | c.5890C>T p.H1964Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51436308; called by muse, mutect2
- ZNF280A | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as rs780225696, COSV57480372; called by muse, mutect2, varscan2
- ZNF423 | c.919C>G p.H307D (on ENST00000563137 / NM_001379286.1; = p.H299D on NM_015069.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV52198974; called by muse, mutect2, varscan2
- ZNF556 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV56913378; called by muse, mutect2, varscan2
- ZNF613 | c.937G>A p.E313K (on ENST00000293471 / NM_001031721.4; = p.E277K on NM_024840.4) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs765295874, COSV53273172; called by muse, mutect2, varscan2
- ZNF839 | c.1174C>T p.H392Y (on ENST00000558850 / NM_001267827.1; = p.H508Y on NM_018335.5) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV51758691; called by muse, mutect2, varscan2
- ZSCAN22 | c.861G>C p.Q287H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV61639456; called by muse, mutect2, varscan2
- FAM78A | c.180_205del p.V61Pfs*91 | Frame Shift Del (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel
- HNF1B | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMT2C | c.12597_12598dup p.H4200Lfs*19 | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- LUM | c.324del p.R110Efs*6 | Frame Shift Del (DEL) | VAF 9/18 reads (50%) | called by mutect2, pindel, varscan2
- MUC2 | c.584C>G p.S195W | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- PRAMEF19 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 102/460 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- TMEM115 | c.694del p.L232Cfs*17 | Frame Shift Del (DEL) | VAF 21/60 reads (35%) | called by mutect2, pindel, varscan2
- USP34 | c.5441dup p.L1814Ffs*44 | Frame Shift Ins (INS) | VAF 3/23 reads (13%) | called by mutect2*, pindel
- AGO4 | c.1029C>T p.I343= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV64618046; called by muse, mutect2, varscan2
- C2CD3 | c.5757C>T p.I1919= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as COSV100487454; called by muse, mutect2, varscan2
- CAMTA1 | c.420C>G p.L140= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV57917143; called by muse, mutect2, varscan2
- CCDC189 | c.924C>T p.L308= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV100079837; called by muse, mutect2, varscan2
- CHERP | c.2196G>A p.R732= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV52226730; called by muse, mutect2, varscan2
- CNPPD1 | c.48C>T p.L16= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV56087132; called by muse, mutect2
- CNTRL | c.3156G>A p.Q1052= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs764428756, COSV53050861; called by muse, mutect2, varscan2
- CYP21A2 | c.1191G>A p.T397= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs775982691, COSV64484917; called by muse, mutect2, varscan2
- CYP3A7 | c.855G>A p.E285= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV60482636; called by muse, mutect2, varscan2
- DLC1 | c.4545C>T p.F1515= (on ENST00000276297 / NM_001348081.2; = p.F1078= on NM_006094.5) | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs750978100, COSV52292585, COSV52318358; called by muse, mutect2, varscan2
- DPPA3 | c.321T>G p.V107= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV61503388; called by muse, mutect2, varscan2
- DUSP8 | c.519G>A p.Q173= | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV59030922; called by muse, varscan2
- FBN3 | c.3357G>C p.L1119= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as COSV54458852, COSV54467819; called by muse, mutect2, varscan2
- GLIS2 | c.1530C>T p.V510= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV52111415; called by muse, mutect2, varscan2
- GNB1L | c.351G>C p.R117= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV61549233; called by muse, mutect2, varscan2
- HCRTR1 | c.171C>T p.F57= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs1388339441, COSV65485030; called by muse, mutect2, varscan2
- INSRR | c.2547C>T p.Y849= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1436248902, COSV63875867; called by muse, mutect2, varscan2
- LCT | c.4017C>T p.F1339= | Silent (SNP) | VAF 68/167 reads (41%) | catalogued as COSV51554484; called by muse, mutect2, varscan2
- LINGO1 | c.1698C>T p.I566= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV62437964; called by muse, mutect2, varscan2
- MELK | c.123C>T p.I41= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV53200946; called by muse, mutect2, varscan2
- MMEL1 | c.285G>A p.V95= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV56524371; called by muse, mutect2, varscan2
- MTHFD2L | c.927C>T p.F309= (on ENST00000395759 / NM_001144978.2; = p.F251= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as rs751828571, COSV57469381; called by muse, mutect2, varscan2
- MTOR | c.6840G>A p.L2280= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV63868641; called by muse, mutect2, varscan2
- NFE2L3 | c.1713G>C p.L571= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV50233945; called by muse, mutect2, varscan2
- NLRP9 | c.2955G>A p.K985= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV60466089, COSV60468293; called by muse, mutect2, varscan2
- OGFR | c.1548G>A p.G516= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV51701108; called by muse, mutect2, varscan2
- OR2AE1 | c.204C>G p.L68= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV60390741; called by muse, varscan2
- OR7G1 | c.483G>C p.L161= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV53318425, COSV99528649; called by muse, mutect2, varscan2
- PCDHGA4 | c.1629G>A p.G543= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs748701559, COSV53998290; called by muse, mutect2, varscan2
- PHF1 | c.1572G>T p.G524= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53382156, COSV53384825; called by muse, mutect2, varscan2
- PROKR2 | c.30C>T p.F10= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV54088242; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.786G>C p.L262= (on ENST00000352766; = p.L139= on NM_181334.5) | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100424692; called by muse, mutect2, varscan2
- PTPRH | c.939C>T p.I313= | Silent (SNP) | VAF 50/152 reads (33%) | catalogued as rs377115239; called by muse, mutect2
- RHBDF1 | c.1782C>T p.I594= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV51957042; called by muse, mutect2, varscan2
- RHPN2 | c.1155C>G p.L385= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs1226237511, COSV54282454; called by muse, mutect2, varscan2
- RRP9 | c.537G>A p.R179= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV51755703; called by muse, mutect2, varscan2
- SIRPD | c.354G>A p.V118= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV67547040; called by muse, mutect2, varscan2
- SLC6A9 | c.1500G>C p.V500= (on ENST00000360584 / NM_201649.4; = p.V446= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV62211571; called by muse, mutect2, varscan2
- TARBP1 | c.4857C>G p.T1619= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV50195899; called by muse, varscan2
- TMEM211 | c.477C>G p.L159= (on ENST00000423535; = p.L88= on NM_001001663.3) | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV66954260; called by muse, mutect2, varscan2
- TOMM40L | c.471G>A p.L157= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV63468915; called by muse, mutect2, varscan2
- TOPBP1 | c.2754G>A p.K918= | Silent (SNP) | VAF 47/132 reads (36%) | catalogued as COSV53439615; called by muse, mutect2, varscan2
- TRABD2A | c.1305C>T p.F435= (on ENST00000409520 / NM_001277053.2; = p.F386= on NM_001080824.3) | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV52874423; called by muse, mutect2, varscan2
- TRAF2 | c.543C>T p.V181= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV56040082; called by muse, varscan2
- TRERF1 | c.1536G>C p.L512= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV61675565; called by muse, mutect2, varscan2
- VAV2 | c.171C>G p.L57= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV64083960; called by muse, mutect2, varscan2
- ATP6V0E2 | chr7:149873948 C>T | 5'Flank (SNP) | VAF 14/26 reads (54%) | catalogued as rs207468794, COSV70416755; called by muse, varscan2
- DST | c.4297-2573C>A | Intron (SNP) | VAF 7/29 reads (24%) | catalogued as COSV55030355; called by muse, mutect2, varscan2
- HEATR6 | c.-1G>C | 5'UTR (SNP) | VAF 9/15 reads (60%) | catalogued as COSV51747690; called by muse, varscan2
- MACF1 | c.15832-9251C>T | Intron (SNP) | VAF 12/45 reads (27%) | catalogued as COSV57134412; called by muse, mutect2, varscan2
- MACF1 | c.15832-9104C>T | Intron (SNP) | VAF 12/34 reads (35%) | catalogued as COSV57134427; called by muse, mutect2, varscan2
- NFATC3 | c.3107-12019C>G | Intron (SNP) | VAF 38/110 reads (35%) | catalogued as COSV60477281; called by muse, mutect2
- NRP2 | c.251+3013C>T | Intron (SNP) | VAF 30/72 reads (42%) | catalogued as COSV55932656; called by muse, mutect2, varscan2
